Gene-level copy-number profile of tumor specimen TCGA-23-1809-01A from TCGA case TCGA-23-1809, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 63.3 years (23,111 days).
Specimen TCGA-23-1809-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.292a1f0d-0e96-48ab-b8c3-4a5b98cd9ca4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1809-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/105a2e4c-5c48-4388-926d-5aa0e3cd4b10

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 559; copy number 2: 9,840; copy number 3: 20,739; copy number 4: 16,090; copy number 5: 4,465; copy number 6: 4,539; copy number 7: 1,605; copy number 8: 1,155; copy number 9: 324; copy number 10: 37; copy number 12: 328; copy number 13: 92; copy number 14: 6; copy number 19: 4; copy number 21: 6; copy number 25: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1809-01A-01D-0559-01): tumor purity 0.8, ploidy 3.71, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:98,134,624–98,453,805, 8 genes: R3HCC1L, LOXL4, AL139241.1, PYROXD2, MIR1287, HPS1, MIR4685, AL139243.1.
- chr10:115,093,365–115,948,999, 1 gene (within-gene range 0–2): ATRNL1.
- chr22:23,059,415–23,164,350, 5 genes: RSPH14, GNAZ, Metazoa_SRP, U7, RAB36.
- chr22:23,179,918–23,180,172, 1 gene: BCRP8.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,436 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:53,413,149–56,524,495, 70 genes, copy number 7 (broad region; genes not listed).
- chr2:88,414,898–89,254,015, 53 genes, copy number 7: RNU6-1007P, RPL38P6, FOXI3, TEX37, AC104134.1, EIF2AK3, EIF2AK3-DT, AC062029.1, RPIA, ANKRD36BP2, MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr3:90,030,284–118,810,836, 335 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr3:187,796,187–193,378,820, 57 genes, copy number 7 (within-gene range 6–7): AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1.
- chr4:49,588,772–54,295,272, 36 genes, copy number 7 (within-gene range 4–7): SNX18P25, DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1.
- chr6:101,181,257–102,070,083, 1 gene, copy number 19 (within-gene range 6–19): GRIK2.
- chr6:102,078,872–104,026,763, 8 genes, copy number 19–25: AP002530.1, AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10.
- chr8:17,156,482–17,800,917, 17 genes, copy number 8 (within-gene range 1–8): ZDHHC2, CNOT7, VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1, MIR548V, AC124069.1, RNA5SP256.
- chr8:17,808,361–17,822,183, 1 gene, copy number 7 (within-gene range 4–7): AC027117.1.
- chr9:9,799,423–11,276,314, 9 genes, copy number 7: AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1.
- chr12:16,989,126–17,711,046, 12 genes, copy number 14–21: SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA.
- chr12:22,008,348–24,967,504, 34 genes, copy number 13: AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1, SOX5, AC087260.1, MIR920, SOX5-AS1, LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2, AC026310.2, AC026310.1, BRI3P2.
- chr12:105,235,290–133,214,832, 747 genes, copy number 7 (broad region; genes not listed).
- chr14:18,333,726–42,989,483, 719 genes, copy number 8–12 (broad region; genes not listed).
- chr16:35,335,277–35,912,516, 56 genes, copy number 7: FRG2HP, RARRES2P9, AGGF1P9, C2orf69P4, LINC01566, FRG2GP, AGGF1P4, FRG2IP, RARRES2P7, AGGF1P5, C2orf69P3, AC018558.4, ZNF971P, AC018558.6, FRG2DP, RARRES2P10, AGGF1P6, AC018558.2, C2orf69P2, AC018558.3, AC018558.7, AC018558.1, TP53TG3HP, AC018558.5, RARRES2P8, AGGF1P7, C2orf69P1, C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr17:47,980,398–50,397,888, 133 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr18:47,390–29,650,440, 521 genes, copy number 7–8 (broad region; genes not listed).
- chr19:22,391,019–24,163,425, 83 genes, copy number 8–13 (within-gene range 5–13) (broad region; genes not listed).
- chr20:87,250–7,146,656, 200 genes, copy number 7 (broad region; genes not listed).
- chr20:33,657,087–34,825,651, 44 genes, copy number 8 (within-gene range 5–8): NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1, DYNLRB1, Y_RNA, MAP1LC3A, PIGU, AL118520.1, NCOA6, TP53INP2, AL109824.1.
- chr22:19,121,529–23,008,356, 300 genes, copy number 8–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 559. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
